Gene-level copy-number profile of tumor specimen TCGA-EK-A2PI-01A from TCGA case TCGA-EK-A2PI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 44.7 years (16,324 days).
Specimen TCGA-EK-A2PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.92383368-b5fa-4014-aa42-f6c0af2c697a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2PI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e1c26771-c7f9-4b6a-9be5-f20ec1e17618

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 223; copy number 2: 7,703; copy number 3: 9,976; copy number 4: 27,365; copy number 5: 6,315; copy number 6: 3,181; copy number 7: 3,666; copy number 8: 229; copy number 9: 33; copy number 10: 903; copy number 11: 123; copy number 16: 91; copy number 18: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2PI-01A-11D-A18H-01): tumor purity 0.81, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:106,863,816–106,904,099, 2 genes: PPIAP24, AL162574.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,160 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,154,863–71,524,107, 77 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr15:73,560,014–101,933,350, 767 genes, copy number 10 (broad region; genes not listed).
- chr18:41,341,319–42,115,538, 8 genes, copy number 9: AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3.
- chr18:52,340,197–58,019,061, 71 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr20:31,257,664–37,527,931, 227 genes, copy number 10–16 (within-gene range 8–16) (broad region; genes not listed).
- chr20:39,655,325–40,854,229, 10 genes, copy number 18: AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484.

Autosomal genes at a single copy (total copy number 1): 223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
